Somatic mutation profile of tumor specimen MBCProject_0582_T1_WES (aliquot MBCProject_0582_T1_WES_1) from CMI case MBCProject_0582, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0582_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3329ea01-4392-433d-9b38-404155e5e2eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0582_SALIVA (Saliva), aliquot MBCProject_0582_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78bca97a-c102-4c72-b376-ca2638983a62

The open-access MAF lists 114 somatic variants for this specimen: 80 protein-altering or splice-affecting, 18 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 18, Intron 6, Nonsense Mutation 5, RNA 5, 3'UTR 3, Splice Region 2, Frame Shift Del 1, 5'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.653T>A p.V218E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52690974, COSV52712839, COSV52761003; called by muse, mutect2, varscan2
- ASXL1 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV60103934, COSV60119071; called by muse, mutect2, varscan2
- BLK | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.539); catalogued as rs751627957; called by muse, mutect2, varscan2
- C1orf94 | c.619G>C p.V207L (on ENST00000488417 / NM_001134734.2; = p.V17L on NM_032884.5) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs367654533; called by muse, mutect2
- C2orf69 | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60666191; called by muse, mutect2
- CDKN2A | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs878853646, CD111993, CD961883, CM960271, COSV58683653, COSV58684450, COSV58705440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.2659G>C p.E887Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs780234826, CM141367, COSV62611731; called by muse, varscan2
- DNAH11 | c.9246G>C p.K3082N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60986129; called by muse, mutect2, varscan2
- FAT3 | c.10129C>G p.H3377D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as COSV53118144; called by muse, mutect2, varscan2
- G3BP2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV62977040; called by muse, mutect2, varscan2
- IGF2BP1 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV51736512; called by muse, mutect2, varscan2
- IPO13 | c.2800C>T p.R934* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs1248953818; called by muse, mutect2
- IRX5 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); catalogued as rs759550123; called by muse, mutect2, varscan2
- KIAA1109 | c.9535G>C p.E3179Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52692884; called by muse, mutect2
- LRRC8A | c.1397C>G p.A466G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV52187873; called by mutect2, varscan2
- MRM3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as rs763804057; called by muse, mutect2, varscan2
- OR2T4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs756078095, COSV63544824; called by muse, mutect2, varscan2
- RPL22L1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs1313186757, COSV55557092, COSV55557427; called by muse, mutect2
- SCN9A | c.901+5G>C | Splice Region (SNP) | VAF 11/43 reads (26%) | catalogued as rs756005334, CS154379; ClinVar: uncertain significance; called by muse, mutect2
- TMEM168 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.784); catalogued as rs763480177; called by muse, mutect2, varscan2
- TMEM229A | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as rs1357204516; called by muse, varscan2
- TRIM54 | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99940676; called by muse, mutect2
- TTN | c.28712C>A p.S9571* (on ENST00000591111; = p.S8644* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV60197728; called by muse, mutect2, varscan2
- UBQLN2 | c.1652C>G p.S551* | Nonsense Mutation (SNP) | VAF 16/276 reads (6%) | catalogued as COSV57740042; called by muse, mutect2
- USP34 | c.8860G>A p.E2954K | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV101277154; called by muse, mutect2
- ZNF407 | c.4732C>T p.Q1578* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV55266928, COSV99996468; called by muse, mutect2, varscan2
- ABCA13 | c.6052A>T p.S2018C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- ABHD11 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- AR | c.1006T>C p.S336P | Missense Mutation (SNP) | VAF 144/230 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ARHGEF5 | c.1441C>G p.Q481E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ASIC5 | c.142C>G p.H48D | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- BCLAF1 | c.2634C>G p.F878L | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.351); called by muse, mutect2
- BIVM-ERCC5 | c.4577G>C p.R1526T | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- BRINP2 | c.532T>A p.S178T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CARMIL1 | c.4070C>G p.S1357C | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); called by muse, mutect2
- CCNE2 | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.057); called by muse, mutect2
- CDC16 | c.406C>G p.R136G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- CDK1 | c.47G>C p.G16A | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CELF5 | c.1042C>G p.Q348E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- COL4A3 | c.3819G>A p.M1273I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPOX | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2
- DGKD | c.1192C>G p.Q398E (on ENST00000264057 / NM_152879.3; = p.Q354E on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- DNAJC16 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- DRICH1 | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- ERVMER34-1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); called by muse, varscan2
- FOXP1 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 11/200 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.068); called by muse, mutect2
- FRMD4B | c.1823C>G p.S608C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- GCC2 | c.2492C>G p.S831C | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPA33 | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- GSPT2 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- HEXA | c.673-3C>T | Splice Region (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- IGLV2-11 | c.52T>A p.W18R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- INPP5J | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- IWS1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.227); called by muse, mutect2
- KALRN | c.3858G>A p.M1286I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2
- KAT6B | c.1184C>G p.S395* | Nonsense Mutation (SNP) | VAF 24/251 reads (10%) | called by muse, mutect2
- KPRP | c.1546C>A p.H516N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGI2 | c.2101C>G p.Q701E | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2
- MUC5B | c.16013G>A p.C5338Y | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NDUFA12 | c.170-1G>C p.X57_splice | Splice Site (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- NGLY1 | c.1859G>A p.R620K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA12 | c.2000G>A p.S667N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); called by muse, mutect2
- PDE11A | c.587T>C p.L196P | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PDLIM3 | c.445G>A p.E149K (on ENST00000284770 / NM_001257963.1; = p.E316K on NM_014476.6) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PGAP3 | c.528C>G p.I176M | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- PHYH | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POLK | c.1858C>G p.Q620E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2
- PTPN7 | c.520_544del p.N174Wfs*44 (on ENST00000495688; = p.N213Wfs*44 on NM_002832.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- RYR1 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SERPINB5 | c.636C>G p.I212M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SMARCAL1 | c.2436C>G p.I812M | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.1); called by muse, mutect2
- SPDYE3 | c.1606C>G p.P536A | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SUPT6H | c.2955G>C p.L985F | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TBCCD1 | c.1238C>G p.T413R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOP2B | c.2704G>C p.D902H (on ENST00000264331 / NM_001330700.2; = p.D897H on NM_001068.3) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- WDHD1 | c.567C>G p.I189M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); called by muse, mutect2
- ZCCHC2 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF200 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ZNF268 | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZNF629 | c.1620G>C p.K540N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- CCNA2 | c.1173C>G p.L391= | Silent (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- DAB2IP | c.3339G>A p.L1113= (on ENST00000408936; = p.L1085= on NM_032552.3) | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- FBN2 | c.1107C>A p.G369= | Silent (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- HBE1 | c.183C>G p.V61= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- HS3ST5 | c.810G>A p.E270= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as rs1337904660; called by muse, mutect2
- LRCH4 | c.1977G>C p.L659= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- METTL3 | c.594G>C p.L198= | Silent (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- MYH11 | c.1506G>A p.E502= | Silent (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- MYLK4 | c.231C>T p.L77= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs147243450, COSV51152265; called by muse, mutect2, varscan2
- NBEAL1 | c.2580G>C p.V860= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- NOD1 | c.2008C>T p.L670= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1506C>T p.H502= | Silent (SNP) | VAF 17/234 reads (7%) | catalogued as rs1206745884, COSV56524421; called by muse, mutect2
- PDE11A | c.588G>A p.L196= | Silent (SNP) | VAF 23/213 reads (11%) | catalogued as COSV53699201; called by muse, mutect2
- RBMXL3 | c.741C>T p.R247= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs892714612, COSV57752185; called by muse, mutect2
- SERPINB11 | c.12C>G p.L4= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV66957083, COSV66957835; called by muse, mutect2
- SLC5A6 | c.600C>A p.I200= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- ST8SIA5 | c.858G>A p.S286= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV59332274; called by muse, mutect2, varscan2
- TBX2 | c.1371G>A p.A457= | Silent (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- AP000769.3 | chr11:65503318 G>C | 5'Flank (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- CEP57L1 | c.745-365G>T | Intron (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- COPS2 | c.372+16C>T | Intron (SNP) | VAF 7/62 reads (11%) | catalogued as rs764643127; called by muse, mutect2, varscan2
- FBXL21P | n.1473G>C | RNA (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- GPATCH1 | c.-10G>A | 5'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- MIS18BP1 | c.1436+164G>A | Intron (SNP) | VAF 5/27 reads (19%) | catalogued as rs1256079354; called by muse, mutect2
- NDUFAF5 | c.*874G>T | 3'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- OR4F13P | n.1198G>C | RNA (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- PMS2CL | n.980G>C | RNA (SNP) | VAF 11/77 reads (14%) | catalogued as rs1262510643; called by muse, mutect2, varscan2
- RPL23AP82 | n.552A>G | RNA (SNP) | VAF 14/170 reads (8%) | catalogued as rs1555937550; called by muse, mutect2, varscan2
- SEC1P | n.590T>C | RNA (SNP) | VAF 10/66 reads (15%) | called by muse, varscan2
- SFTPA2 | c.-23-188G>A | Intron (SNP) | VAF 6/154 reads (4%) | called by muse, mutect2
- ST20-MTHFS | c.-12+70T>C | Intron (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- TBC1D22A | c.1015+3264G>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- UBR7 | c.*1280G>A | 3'UTR (SNP) | VAF 8/79 reads (10%) | catalogued as rs969894232; called by muse, mutect2, varscan2
- UBR7 | c.*1281A>T | 3'UTR (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
